Somatic mutation profile of tumor specimen CUPP-B493-TTP1-A (aliquot CUPP-B493-TTP1-A-1-0-D-A82Z-47) from CCG case CUPP-B493, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IV; Age at diagnosis: 59.3 years (21,646 days).
Specimen CUPP-B493-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82b06e66-ff86-4a9f-a8f7-2ba85e7402ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B493-NT1-A (FFPE Scrolls), aliquot CUPP-B493-NT1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99c3fd12-bc97-4740-83ca-1d79ee2b8bff

The open-access MAF lists 87 somatic variants for this specimen: 65 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 17, Intron 4, Frame Shift Ins 2, Nonsense Mutation 1, Frame Shift Del 1, RNA 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as rs532627156, COSV53048314; called by mutect2, varscan2
- BRCA2 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs752886421; ClinVar: uncertain significance; called by mutect2, varscan2
- C1orf35 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs768840354; called by mutect2, varscan2
- CCDC32 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367681812; called by muse, mutect2, varscan2
- CCNL2 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs764125593; called by mutect2, varscan2
- CDC42BPG | c.4021G>C p.D1341H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430141961; called by mutect2, varscan2
- CHRNA7 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1296944199, COSV100180621; called by mutect2, varscan2
- DIDO1 | c.6184G>T p.D2062Y | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV56615016; called by mutect2, varscan2
- ERBB2 | c.774C>G p.F258L | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV54078623; called by muse, mutect2, varscan2
- FKBP6 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as rs1275158987; called by muse, mutect2, varscan2
- GATA6 | c.531_545del p.A179_A183del | In Frame Del (DEL) | VAF 27/54 reads (50%) | catalogued as rs777216159; called by mutect2, varscan2
- HPS6 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.368); catalogued as rs1450101908, COSV54626308; called by muse, mutect2, varscan2
- ICE1 | c.4058G>C p.G1353A | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56829677; called by muse, mutect2, varscan2
- INPP5D | c.499C>T p.R167* (on ENST00000445964 / NM_001017915.3; = p.R166* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 31/98 reads (32%) | catalogued as rs753207715, COSV64036812; called by muse, mutect2, varscan2
- KMT2B | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs748073369; called by muse, varscan2
- LAMB2 | c.4363C>T p.R1455W | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901971113, COSV59734847; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LZTR1 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs375451574; called by muse, mutect2, varscan2
- MAST3 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs1410386265, COSV53218937; called by muse, mutect2, varscan2
- NPHP3 | c.3290A>G p.N1097S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157229330; called by muse, mutect2, varscan2
- NRG1 | c.205A>C p.K69Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs747804470; called by muse, mutect2, varscan2
- NYAP1 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as rs760779356, COSV55720835; called by muse, varscan2
- OR2W3 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100831867; called by muse, varscan2
- PADI3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs759343182; called by mutect2, varscan2
- PDZD11 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV52103808; called by muse, mutect2, varscan2
- PNCK | c.121G>A p.V41M (on ENST00000340888 / NM_001366975.1; = p.V124M on NM_001039582.3) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61742464; called by muse, mutect2, varscan2
- POP4 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1047470546; called by muse, varscan2
- RTL10 | c.256A>G p.M86V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs755351788; called by mutect2, varscan2
- SIX4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1210344312, COSV53668653; called by muse, mutect2, varscan2
- SLCO1B3 | c.833dup p.P280Afs*6 | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | catalogued as rs751405974; called by mutect2, varscan2
- TMEM139 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as COSV100130870; called by mutect2, varscan2
- TTC7A | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.302); catalogued as COSV55409146; called by muse, mutect2, varscan2
- TTN | c.27595C>T p.R9199C (on ENST00000591111; = p.R8272C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | PolyPhen probably damaging (0.982); catalogued as rs751958797, COSV100638442; called by mutect2, varscan2
- USP31 | c.3451G>A p.D1151N | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as rs1312791005, COSV54851082; called by mutect2, varscan2
- VSIG2 | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.035); catalogued as COSV52519653; called by mutect2, varscan2
- AOPEP | c.88T>G p.L30V | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C3orf38 | c.349A>C p.T117P | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CA12 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.005); called by mutect2, varscan2
- CCDC168 | c.7674A>T p.K2558N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.636); called by mutect2, varscan2
- CLK1 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL27A1 | c.2959C>T p.P987S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DCAF5 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- DNAJB8 | c.64G>C p.A22P | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FOS | c.443A>T p.K148M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR84 | c.762T>G p.I254M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.382); called by mutect2, varscan2
- GRIK3 | c.2069G>A p.G690E | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC31 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by mutect2, varscan2
- MGA | c.7393dup p.T2465Nfs*6 (on ENST00000219905 / NM_001164273.1; = p.T2256Nfs*6 on NM_001080541.2) | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | called by mutect2, varscan2
- MGRN1 | c.1066T>C p.C356R | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by mutect2, varscan2
- MOV10 | c.2245G>A p.G749R | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.16); called by mutect2, varscan2
- NBPF26 | c.4271T>A p.V1424E (on ENST00000620612; = p.V1162E on NM_001351372.1) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- NLK | c.677T>G p.L226R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- NOXRED1 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.123); called by mutect2, varscan2
- ORAI2 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by mutect2, varscan2
- PDZRN4 | c.1523T>C p.L508S (on ENST00000402685 / NM_001164595.2; = p.L250S on NM_013377.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRSS8 | c.10A>G p.K4E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, varscan2
- SEMA4A | c.2071T>A p.F691I | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- SH3BP5 | c.271del p.I91Lfs*69 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, varscan2
- SLC4A8 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLF2 | c.1757C>G p.S586C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.614); called by mutect2, varscan2
- SPRR4 | c.157C>A p.Q53K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); called by mutect2, varscan2
- ST3GAL3 | c.351C>G p.F117L (on ENST00000361392 / NM_174964.4; = p.F102L on NM_006279.5) | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TMEM134 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by mutect2, varscan2
- TRHDE | c.982T>C p.S328P | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- TTN | c.76894C>G p.P25632A (on ENST00000591111; = p.P18208A on NM_003319.4) | Missense Mutation (SNP) | VAF 16/99 reads (16%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF443 | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, varscan2
- CBARP | c.765G>C p.A255= (on ENST00000382477; = p.A235= on NM_152769.3) | Silent (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- CDK5R2 | c.579C>T p.F193= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as rs769669157, COSV56937486; called by muse, mutect2, varscan2
- CDR2L | c.408G>A p.L136= | Silent (SNP) | VAF 42/144 reads (29%) | called by mutect2, varscan2
- CDR2L | c.441G>A p.E147= | Silent (SNP) | VAF 43/128 reads (34%) | called by mutect2, varscan2
- HROB | c.1686C>A p.L562= | Silent (SNP) | VAF 12/46 reads (26%) | called by mutect2, varscan2
- MGAM | c.1620G>A p.S540= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs782097584, COSV101527533, COSV72075266; called by mutect2, varscan2
- MKI67 | c.9204C>T p.N3068= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs575407769, COSV64076269; called by muse, mutect2, varscan2
- NOX4 | c.330T>C p.V110= | Silent (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- RTL10 | c.255C>T p.H85= | Silent (SNP) | VAF 6/43 reads (14%) | called by mutect2, varscan2
- SBF2 | c.180G>A p.R60= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs757248945; called by mutect2, varscan2
- SLC30A3 | c.795C>T p.A265= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs114829262; called by muse, mutect2, varscan2
- SLC35E3 | c.54C>T p.L18= | Silent (SNP) | VAF 7/56 reads (13%) | called by mutect2, varscan2
- TRRAP | c.1221C>T p.D407= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs781819690; called by mutect2, varscan2
- UGT1A6 | c.1350G>C p.P450= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as rs368860136, COSV100530391; called by muse, mutect2, varscan2
- USP21 | c.1134G>A p.L378= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV99237128; called by mutect2, varscan2
- ZNF804B | c.2679C>T p.S893= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs757534983; called by muse, mutect2, varscan2
- ZSWIM1 | c.612A>T p.S204= | Silent (SNP) | VAF 16/100 reads (16%) | called by muse, varscan2
- DCHS2 | n.6625A>T | RNA (SNP) | VAF 28/59 reads (47%) | called by mutect2, varscan2
- DIAPH3 | c.2737+24T>G | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as rs1163939201; called by muse, varscan2
- GRSF1 | c.357+100G>C | Intron (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2
- GRSF1 | c.357+99C>A | Intron (SNP) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- OPRM1 | c.1164+1834G>C | Intron (SNP) | VAF 28/89 reads (31%) | catalogued as rs199942335; called by muse, mutect2, varscan2
